Somatic mutation profile of tumor specimen TCGA-D9-A6EG-06A (aliquot TCGA-D9-A6EG-06A-12D-A32N-08) from TCGA case TCGA-D9-A6EG, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.0 years (20,824 days).
Specimen TCGA-D9-A6EG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8d271cc1-6906-468a-9e3d-7fe18c92a2c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D9-A6EG-10A (Blood Derived Normal), aliquot TCGA-D9-A6EG-10A-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12263a05-b81e-4840-bd9e-c7030a9f7542

The open-access MAF lists 94 somatic variants for this specimen: 60 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 30, Nonsense Mutation 8, Splice Site 2, Frame Shift Del 2, Frame Shift Ins 2, RNA 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/114 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CTNNB1 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 25/81 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs121913407, COSV62687880, COSV62689248, COSV62696859; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.116G>A p.W39* | Nonsense Mutation (SNP) | VAF 30/37 reads (81%) | catalogued as rs775683960, CM033045, COSV99635311; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs757720814, COSV99841532; called by muse, mutect2, varscan2
- AGXT2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 63/130 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.741); catalogued as COSV51484069, COSV99183846; called by muse, mutect2, varscan2
- APOB | c.1343C>T p.A448V | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs148167725; called by muse, mutect2, varscan2
- ASTN2 | c.2363T>G p.V788G (on ENST00000313400 / NM_001365069.1; = p.V737G on NM_014010.5) | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as COSV100530276; called by muse, mutect2, varscan2
- CBX3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs1208793747, COSV61761621; called by muse, mutect2, varscan2
- CD93 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as COSV99849180, COSV99849574; called by muse, mutect2, varscan2
- CHD8 | c.1489G>T p.E497* (on ENST00000646647 / NM_001170629.2; = p.E218* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as rs1555318031, COSV101303213; called by muse, mutect2, varscan2
- CILP | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV56022522; called by muse, mutect2, varscan2
- CNTNAP1 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs755070825, COSV99226140, COSV99226997; called by muse, mutect2, varscan2
- COPB1 | c.1636C>T p.L546F | Missense Mutation (SNP) | VAF 130/225 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.159); catalogued as rs202139831; called by muse, mutect2, varscan2
- DCC | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as COSV59099737; called by muse, mutect2, varscan2
- DDRGK1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100621531; called by muse, mutect2, varscan2
- DDRGK1 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1386595070, COSV100621532; called by muse, mutect2, varscan2
- DHRS3 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66108456; called by muse, mutect2, varscan2
- DNAH11 | c.7549A>G p.T2517A | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV60981945; called by muse, mutect2, varscan2
- DPF3 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100818687; called by mutect2, varscan2
- GABRG1 | c.323A>G p.E108G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99778740; called by muse, mutect2, varscan2
- GABRG1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV99778742; called by muse, mutect2, varscan2
- HEPACAM2 | c.1115G>A p.W372* (on ENST00000394468 / NM_001039372.4; = p.W360* on NM_198151.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/100 reads (26%) | catalogued as rs1000322300, COSV59064188; called by muse, mutect2, varscan2
- HLA-DOB | c.725G>A p.G242E | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV71270939; called by muse, mutect2
- IPO7 | c.1948+2T>C p.X650_splice | Splice Site (SNP) | VAF 23/76 reads (30%) | catalogued as COSV100797846; called by muse, mutect2, varscan2
- KCTD19 | c.2552C>T p.A851V | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100431224; called by muse, mutect2, varscan2
- KIF14 | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 90/151 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100951080; called by muse, mutect2, varscan2
- KMT2D | c.6748C>T p.P2250S | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV99985688; called by muse, mutect2, varscan2
- LRPPRC | c.1862A>G p.N621S | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99581456; called by muse, mutect2, varscan2
- LY86 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV57911127; called by muse, mutect2, varscan2
- MIB2 | c.2110C>G p.P704A | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100599040; called by muse, mutect2, varscan2
- MYH1 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56853661, COSV56854263; called by muse, mutect2, varscan2
- NAP1L2 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs1428399931, COSV65172680; called by muse, mutect2
- NKAIN1 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV99744757; called by muse, mutect2, varscan2
- NRG2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as rs749464757, COSV56833457, COSV56834647; called by muse, mutect2, varscan2
- OR4N5 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs764860630, COSV61321288; called by muse, mutect2, varscan2
- OR51L1 | c.677C>G p.T226S | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV100386492, COSV58625478; called by muse, mutect2, varscan2
- PAFAH1B1 | c.967T>G p.W323G | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101250453; called by muse, mutect2, varscan2
- PDE4DIP | c.4217G>A p.G1406E | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as rs1553594329, COSV57724892; called by muse, mutect2, varscan2
- PDK4 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 32/130 reads (25%) | catalogued as rs1237699148, COSV50010897; called by muse, mutect2, varscan2
- PUS7L | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100786608; called by muse, mutect2, varscan2
- RAVER1 | c.397C>G p.L133V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99349267; called by muse, mutect2, varscan2
- RFLNA | c.253C>T p.R85W (on ENST00000546355 / NM_001365156.1; = p.R4W on NM_181709.4) | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201197146; called by muse, mutect2, varscan2
- RYR3 | c.5830C>T p.Q1944* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV101214518; called by muse, mutect2, varscan2
- SLC1A1 | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 104/129 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99261589; called by muse, mutect2, varscan2
- SNAP91 | c.2589G>A p.M863I | Missense Mutation (SNP) | VAF 32/41 reads (78%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.577); catalogued as COSV99536586; called by muse, mutect2, varscan2
- SYTL4 | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99343329; called by muse, mutect2, varscan2
- TCF25 | c.1727C>T p.T576I | Missense Mutation (SNP) | VAF 137/350 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1233047306, COSV99643433; called by muse, mutect2, varscan2
- TEX15 | c.3911C>T p.P1304L (on ENST00000256246; = p.P1687L on NM_001350162.2) | Missense Mutation (SNP) | VAF 99/169 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.357); catalogued as COSV99822116; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1564-1G>A p.X522_splice | Splice Site (SNP) | VAF 34/114 reads (30%) | catalogued as COSV99163018; called by muse, mutect2, varscan2
- TRMT6 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99177621; called by muse, mutect2, varscan2
- TTN | c.8251G>A p.E2751K (on ENST00000591111; = p.E2705K on NM_003319.4) | Missense Mutation (SNP) | VAF 79/173 reads (46%) | PolyPhen benign (0.033); catalogued as COSV100629615; called by muse, mutect2, varscan2
- TTYH3 | c.577G>C p.V193L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.046); catalogued as COSV99350144; called by mutect2, varscan2
- ZNF217 | c.1518T>G p.Y506* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | catalogued as COSV100184837; called by muse, mutect2, varscan2
- ZNF354B | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1242065475, COSV100483138; called by muse, mutect2, varscan2
- ZNF496 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1447553209, COSV99666153; called by muse, mutect2, varscan2
- ZNF582 | c.418C>T p.H140Y | Missense Mutation (SNP) | VAF 78/245 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs532568887, COSV100018953; called by muse, mutect2, varscan2
- BBS10 | c.746_749dup p.A251Pfs*5 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.1798del p.E600Kfs*30 | Frame Shift Del (DEL) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
- PTPRR | c.377dup p.N126Kfs*39 | Frame Shift Ins (INS) | VAF 31/97 reads (32%) | called by mutect2, pindel, varscan2
- ZNF703 | c.234_237del p.S78Rfs*62 | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | called by mutect2, varscan2
- AHNAK | c.12402T>G p.V4134= | Silent (SNP) | VAF 88/110 reads (80%) | catalogued as COSV99949550; called by muse, mutect2, varscan2
- ARHGEF11 | c.75C>T p.R25= | Silent (SNP) | VAF 43/198 reads (22%) | catalogued as COSV100810420; called by muse, mutect2, varscan2
- ATP11A | c.498C>T p.F166= | Silent (SNP) | VAF 44/90 reads (49%) | catalogued as COSV52126823; called by muse, mutect2, varscan2
- CCDC151 | c.330T>C p.T110= | Silent (SNP) | VAF 111/255 reads (44%) | catalogued as COSV99371939; called by muse, mutect2, varscan2
- COL20A1 | c.288C>T p.F96= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs371649528; called by muse, mutect2, varscan2
- DUXA | c.255G>A p.Q85= | Silent (SNP) | VAF 97/148 reads (66%) | catalogued as COSV101617158; called by muse, mutect2, varscan2
- FREM1 | c.5535G>A p.V1845= | Silent (SNP) | VAF 45/55 reads (82%) | catalogued as COSV66533583; called by muse, mutect2, varscan2
- GPR50 | c.1614G>A p.E538= | Silent (SNP) | VAF 91/104 reads (88%) | catalogued as rs745788973, COSV99506658; called by muse, mutect2, varscan2
- GRB7 | c.189C>T p.S63= | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as COSV58448070; called by muse, mutect2, varscan2
- HNRNPUL1 | c.102G>A p.Q34= | Silent (SNP) | VAF 13/18 reads (72%) | catalogued as COSV99647601; called by muse, mutect2, varscan2
- KIAA1549 | c.5121C>T p.T1707= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as rs371885622, COSV99650750; called by muse, mutect2, varscan2
- KLF4 | c.1353G>A p.T451= | Silent (SNP) | VAF 71/179 reads (40%) | catalogued as rs774893122, COSV65928605; called by muse, mutect2, varscan2
- LRCH4 | c.549C>T p.S183= | Silent (SNP) | VAF 60/102 reads (59%) | catalogued as COSV53828848; called by muse, mutect2, varscan2
- LY9 | c.810A>C p.A270= | Silent (SNP) | VAF 114/167 reads (68%) | catalogued as COSV99627430; called by muse, mutect2, varscan2
- MAP1S | c.1827C>T p.P609= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100141233; called by muse, mutect2, varscan2
- MAP2K1 | c.387C>T p.F129= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV61069266, COSV61074053; called by muse, mutect2, varscan2
- MROH8 | c.1317G>A p.K439= | Silent (SNP) | VAF 111/238 reads (47%) | catalogued as COSV99457914; called by muse, mutect2, varscan2
- MYB | c.1128C>T p.I376= | Silent (SNP) | VAF 29/35 reads (83%) | catalogued as rs780660118, COSV57196753; called by muse, mutect2, varscan2
- PLB1 | c.3447C>T p.N1149= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as COSV100579888; called by muse, mutect2, varscan2
- PRIMA1 | c.285C>T p.I95= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100301460; called by muse, mutect2, varscan2
- RPTN | c.1311C>T p.S437= | Silent (SNP) | VAF 404/1947 reads (21%) | catalogued as rs1301361053, COSV100285768; called by muse, mutect2, varscan2
- SCN10A | c.3561G>A p.E1187= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs570037688, COSV101479536; called by muse, mutect2, varscan2
- SLC13A3 | c.1470C>T p.I490= | Silent (SNP) | VAF 74/186 reads (40%) | catalogued as COSV99287242; called by muse, mutect2, varscan2
- SLC52A1 | c.444C>T p.F148= | Silent (SNP) | VAF 55/126 reads (44%) | catalogued as COSV99643533; called by muse, mutect2, varscan2
- SND1 | c.165T>G p.R55= | Silent (SNP) | VAF 45/161 reads (28%) | catalogued as COSV100691082; called by muse, mutect2, varscan2
- SYNE2 | c.20457C>T p.P6819= | Silent (SNP) | VAF 30/72 reads (42%) | catalogued as rs751852545, COSV59961111; ClinVar: likely benign; called by muse, mutect2, varscan2
- TEX264 | c.156C>T p.F52= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as COSV100392753; called by muse, mutect2, varscan2
- TOX4 | c.1845C>T p.N615= | Silent (SNP) | VAF 57/111 reads (51%) | catalogued as COSV99398602; called by muse, mutect2, varscan2
- TTYH3 | c.576G>A p.A192= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1347327160, COSV99350138; called by mutect2, varscan2
- VAV1 | c.804G>A p.Q268= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs760222375, COSV100409473; called by muse, mutect2, varscan2
- C3P1 | n.3439C>T | RNA (SNP) | VAF 51/120 reads (43%) | catalogued as rs376707855; called by muse, mutect2, varscan2
- IGF2 | c.326-492C>T | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as COSV100324227; called by muse, mutect2, varscan2
- NBR2 | n.420C>T | RNA (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
- NIN | chr14:50723550 G>A | 3'Flank (SNP) | VAF 45/100 reads (45%) | catalogued as rs1315946449, COSV55389648; called by muse, mutect2, varscan2
